Surgical pathology report (de-identified scan), TCGA case TCGA-FX-A3RE, project TCGA-SARC (Sarcoma), tissue source site International Genomics Consortium, specimen TCGA-FX-A3RE-01A (Primary Tumor).

[page 1 of 4]
Sex: Female
D.O.B.:
MRN #:
Ref Physician:

(Age)

SPECIMEN

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

*** AMENDED REPORT ***

CORRECTED REPORT:

This report is issued to reflect a change in the final diagnosis section. Part L of the final diagnosis was omitted.

- L. Right pelvic side wall, biopsy:
Negative for malignancy.

The correction does not modify the previous diagnostic information.

Report issued by:

Level of Significance	3/2/12	3/13/12

DIAGNOSIS

DIAGNOSIS:

- A. Left ovary and fallopian tube, excision:
Leiomyosarcoma.
Size: 20.0 x 17.0 x 1.5 cm.
No definitive ovarian parenchyma or fallopian tube tissue is identified in the specimen.
Frozen section diagnosis confirmed.
- B. Left pelvic sidewall, biopsy:
Tumor present.
- C. Right pelvic retroperitoneal nodule, excision:
Tumor present with adjacent lymph node.
- D. Right ovary and fallopian tube, excision:
Features consistent with leiomyosarcoma.
Size: 11.0 x 10.0 x 8.7 cm.
Portion of fallopian tube identified.
- E. Retroperitoneal mesenteric mass, excision:
Leiomyosarcoma.
Size: 13.0 x 11.0 x 7.5 cm.
Frozen section diagnosis confirmed.
- F. Right lower periaortic lymph nodes, excision:
Four lymph nodes, negative for metastatic disease.
- G. Right pelvic lymph nodes, excision:
Ten lymph nodes, negative for metastatic disease.
- H. Left periaortic lymph nodes, excision:
Four lymph nodes, negative for metastatic disease.
- I. Left pelvic lymph nodes, excision:
Four lymph nodes, negative for metastatic disease.
- J. Anterior cul-de-sac, biopsy:
Negative for malignancy.
- K. Left pelvic sidewall, biopsy:
Negative for malignancy.
- M. Posterior cul-de-sac, biopsy:
Negative for malignancy.

ICD-0-3

leiomyosarcoma, NOS
8890/3

Site: ovary

C56.9

3-30-12 RD

[page 2 of 4]
- N. Right gutter, biopsy:
Negative for malignancy.
- O. Left gutter, biopsy:
Negative for malignancy.
- P. Omentum, excision:
Negative for malignancy.

Electronic Signature:

COMMENTS:

Appropriately controlled immunohistochemical stains were performed on block A2 with the following results:

Caldesmin: strongly positive in lesional cells.
Calretinin: negative in lesional cells.
CD10: negative in lesional cells.
EMA: negative in lesional cells.
Inhibin: negative in lesional cells.
Pancytokeratin: negative in lesional cells.
Smooth muscle actin: positive in lesional cells.
Vimentin: negative in lesional cells.
S100: negative in lesional cells.
Melan-A: negative in lesional cells.

Appropriately controlled immunohistochemical stains were performed on block A4 with the following results:

Caldesmin: focally weakly positive in lesional cells.
Calretinin: negative in lesional cells.
CD10: negative in lesional cells.
EMA: negative in lesional cells.
Inhibin: negative in lesional cells.
Pancytokeratin: negative in lesional cells.
Smooth muscle actin: negative in lesional cells.
Vimentin: focally weakly positive in lesional cells.
S100: negative in lesional cells.
Melan-A: negative in lesional cells.

A7: Actin: positive in tumor.
Myogenin: negative in tumor.

These findings are consistent with a smooth muscle neoplasm. There is focally significant atypia with necrosis and increased mitotic activity. These findings are consistent with leiomyosarcoma. The more poorly-differentiated component as evidenced in block A4 shows less of a typical staining pattern, but this is not unusual given the poorly differentiated nature.

[page 3 of 4]
CLINICAL HISTORY:

Preoperative Diagnosis: Status-post hysterectomy-probably subtotal ??(cervix-corpus only) large pelvic mass, suspected stage IIIc ovarian carcinoma

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Left tube and ovary with frozen section
- B. Left pelvic side wall
- C. Right pelvic retroperitoneal nodule
- D. Right ovary and tube
- E. Retroperitoneal mesenteric mass with frozen section
- F. Right lower paraaortic lymph node
- G. Right pelvic lymph node
- H. Left paraaortic lymph node
- I. Left pelvic lymph nodes
- J. Anterior cul-de-sac
- K. Left pelvic side wall
- L. Right pelvic side wall
- M. Posterior cul-de-sac
- N. Right gutter
- O. Left gutter
- P. Omentum

SPECIMEN DATA**GROSS DESCRIPTION:**

Specimen is received in sixteen containers labeled with the patients name

A. Container A is additionally labeled 'left tube and ovary' and contains 1,490 gram purple-pink nodular tissue consistent with ovary having dimensions of 20.0 x 17.0 x 11.5 cm. After careful inspection a discrete fallopian tube is not identified. Specimen is sectioned to reveal a multicystic and solid cut surface. The cyst features smooth to wrinkled inner linings and contains pink-tan hemorrhagic fluid. Solid areas yellow-tan nodular and homogenous with simple areas of hemorrhage and dusky discoloration. Normal appearing ovarian stroma is not identified. Representative sections are submitted for frozen section with the residual entirely resubmitted for permanent section in cassette A1 labeled. Additional representative sections are submitted in cassettes A2-10. Additional, yellow and green cassettes are submitted for 1 labeled

B. Container B is additionally labeled 'left pelvic side wall' and contains a 4.5 x 3.5 x 3.3 cm purple gray and glistening rubbery soft tissue and sectioned to reveal a gray-white firm and glistening cut surface consistent with tumor. Representative sections are submitted in cassettes B1 and 2 labeled

C. Container C is additionally labeled 'right pelvic retroperitoneal nodule' and contains a 2.3 x 1.7 x 1.0 cm encapsulated gray-white nodule which features adherent yellow-tan fibrofatty soft tissue. The nodule features a gray-white firm and glistening cut surface consisting of tumor. The specimen is entirely submitted in cassettes C1 and C2 labeled

D. Container D is additionally labeled 'right ovary and tube' and contains a 477.1 gram purple gray encapsulated nodular soft tissue consistent with ovary. This specimen has overall dimensions of 11.0 x 10.0 x 8.7 cm. On close examination, a 4.0 cm in length by 0.6 cm in diameter distorted edematous fallopian tube segment is identified adherent to the outer surface. Sectioning reveals clear fluid within the lumen. Discrete masses are not identified. The ovary features no surface excrescences. Sectioning reveals a yellow-tan whorled, fibrous cut surface with a central area of pink-tan hemorrhage and dusky discoloration. A 2.0 x 1.5 x 1.5 cm multiloculated cyst is also identified on the cut surface. The cyst contains a pink-tan fluid and features smooth to wrinkled inner linings. Normal appearing ovarian stroma is not identified. Representative sections are submitted in cassettes D1-10 labeled as designated as follows: 1 - cross-sections of fallopian tube; 2-10 - ovary.

E. Container E is additionally labeled 'retroperitoneal mesenteric mass' and contains a 438.5 gram, 13.0 x 11.0 x 7.5 cm encapsulated pink-tan nodule. Sectioning reveals a yellow-tan whorled and glistening cut surface with foci of purple-pink dusky discoloration and hemorrhage. Representative sections are submitted for frozen section with the residual entirely resubmitted for permanent section in cassette E1 labeled

F. Container F is additionally labeled 'right lower paraaortic lymph node' and contains a 3.8 x 2.0 x 1.5 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation, four firm fatty possible lymph nodes are identified ranging from 0.2 up to 1.7 cm in greatest dimension. They are entirely submitted in cassettes F1 and 2 labeled designated as follows: F1 - one whole possible lymph node; F2 - three whole possible lymph nodes.

G. Container G is additionally labeled 'right pelvic lymph node' and contains a 5.5 x 4.3 x 1.8 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation, multiple firm fatty possible lymph nodes are identified ranging from 0.3 up to 2.5 cm in greatest dimension. They are entirely submitted in cassettes G1 and G2 labeled designated as follows: G1 - six whole possible lymph nodes; 2 - four whole possible lymph nodes.

H. Container H is additionally labeled 'left paraaortic lymph node' and contains a 3.3 x 1.8 x 1.2 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation, four firm fatty possible lymph nodes are identified ranging from 0.6 up to 1.5 cm in greatest dimension. They are entirely submitted in cassettes H1 and 2 labeled designated as follows: H1 - two whole possible lymph nodes; H2 - two whole possible bisected lymph nodes

[page 4 of 4]
(one inked).

I. Container I is additionally labeled 'left pelvic lymph nodes' and contains a 3.0 x 2.0 x 1.5 cm yellow-tan fibrofatty soft tissue. On palpation, four firm fatty possible lymph nodes are identified ranging from 0.2 up to 0.8 cm in greatest dimension. They are entirely submitted in cassette I labeled

J. Container J is additionally labeled 'anterior cul-de-sac' and contains a 0.6 cm pink-tan glistening soft tissue entirely submitted in cassette J labeled

K. Container K is additionally labeled '#11' and contains a 1.7 x 1.0 x 0.9 cm purple gray fibromembranous soft tissue surfaced by yellow-tan adipose tissue. The specimen is bisected and entirely submitted in cassette K labeled

L. Container L is additionally labeled '#12' and contains a 1.0 x 0.6 x 0.4 cm purple gray glistening soft tissue entirely submitted in cassette L labeled

M. Container M is additionally labeled 'posterior cul-de-sac' and contains a 0.4 cm yellow gray glistening soft tissue entirely submitted in cassette M labeled

N. Container N is additionally labeled '#14' and contains a 2.8 x 2.0 x 0.7 cm yellow-tan fibrofatty soft tissue. No nodules or lesions are identified. Specimen is sectioned and entirely submitted in cassette N labeled

O. Container O is additionally labeled 'left gutter' and contains a 0.9 x 0.7 x 0.4 cm yellow-tan pink rubbery and glistening soft tissue entirely submitted in cassette O labeled

P. Container P is additionally labeled 'omentum' and contains a 27.0 x 8.0 x 1.5 cm yellow-tan finely lobulated fibroadipose tissue consistent with omentum. Sectioning reveals a yellow-tan greasy cut surface. No nodules or lesions are identified. Representative sections are submitted in cassettes P1-4 labeled

Source: NCI Genomic Data Commons file 21b44ce5-e40b-4563-98e0-9ae5bd3fb377 (TCGA-FX-A3RE.1484B57C-04AD-42FE-BBEC-FEBCB3E4E120.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).